Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UQ-01A (Primary Tumor).

(MM/DD/YYYY)

ICD O-3
Adenocarcinoma, mucinous
endocervical type 848213
Cervix NOS C53.9

9/3/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

- 1-) Previous surgical scar:
- Cicatricial fibrosis of the dermis.
- 3-) Right iliac obturator lymph nodes:
- Free of neoplasia (0/2).
- 4-) Right obturator lymphadenectomy:
- Lymph nodes free of neoplasia (0/10).
- 5-) Left iliac obturator lymphadenectomy:
- Lymph nodes free of neoplasia (0/10).
- 6-) Uterus + parametria + Fallopian tubes + vaginal cuff:
- Moderately differentiated mucinous adenocarcinoma of endocervical type, measuring 4.0cm of maximum extension and 1.5cm of maximum depth of invasion.
- The infiltrative tumor is present in the anterior half of the uterine cervix.
- Presence of foci of adenocarcinoma in situ in the posterior wall of the cervix.
- The tumor infiltrates almost all of the anterior cervical stromal thickness, being less than 1mm distant from the circumferential anterior surgical margin.
- Isthmus, uterine corpus and vagina free of neoplasia.
- No indubitable focus of angiolymphatic and perineural infiltration was observed.
- Vaginal margin free of neoplasia.
- Parametria free of neoplasia.
- Leiomyomas in submucosal, subserosal and intramural topographies.
- Fallopian tubes free of neoplasia.

Source: NCI Genomic Data Commons file dd0d1aff-316f-470c-b0f5-753ce5adeee4 (TCGA-VS-A9UQ.AF3A1FB4-1FC6-4CB7-93EF-0E3E2FEE3E8B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).